Somatic mutation profile of tumor specimen MP2PRT-PAUITP-TMP1-A (aliquot MP2PRT-PAUITP-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUITP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,712 days).
Specimen MP2PRT-PAUITP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b65ca34-a8ea-440b-996d-2c876fd2d42e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUITP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUITP-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df71c1c-a18f-472c-9032-bc6386e36ac9

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 181/390 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS1 | c.248A>C p.Q83P | Missense Mutation (SNP) | VAF 253/1153 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV53168711; called by muse, mutect2, varscan2
- ANKRD9 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 300/664 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1346756107; called by muse, mutect2, varscan2
- FGFR1 | c.1112C>T p.S371L (on ENST00000447712 / NM_023110.3; = p.S369L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs961818413, COSV58334512; called by muse, mutect2, varscan2
- KIFC2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 178/408 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283615889; called by muse, mutect2, varscan2
- OR8J1 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 265/624 reads (42%) | catalogued as COSV57318683; called by muse, mutect2, varscan2
- RYR3 | c.12026G>A p.R4009H (on ENST00000389232; = p.R4010H on NM_001036.6) | Missense Mutation (SNP) | VAF 221/488 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202140253, COSV66803544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPYL6 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 237/586 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs973521434; called by muse, mutect2, varscan2
- VEGFC | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs368339476; called by muse, mutect2, varscan2
- DISP2 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 55/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTF2IRD2 | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 169/759 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406870 del ATTCACAGTGTTACAAGCCATAACAAA | Missense Mutation (DEL) | VAF 47/158 reads (30%) | called by pindel, varscan2
- NUCB2 | c.341_350delinsCCC p.L114Sfs*13 | Frame Shift Del (DEL) | VAF 96/316 reads (30%) | called by pindel, varscan2*
- PHYHIPL | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AC231657.3 | c.696C>T p.G232= | Silent (SNP) | VAF 365/724 reads (50%) | catalogued as rs782077354; called by muse, mutect2, varscan2
- DSCAML1 | c.6171C>T p.T2057= (on ENST00000321322; = p.T1997= on NM_020693.4) | Silent (SNP) | VAF 120/278 reads (43%) | catalogued as rs781772778; called by muse, mutect2, varscan2
- GPR179 | c.3813T>C p.S1271= (on ENST00000621958; = p.S1270= on NM_001004334.4) | Silent (SNP) | VAF 321/662 reads (48%) | called by muse, mutect2, varscan2
- SURF4 | c.147C>T p.S49= | Silent (SNP) | VAF 237/520 reads (46%) | catalogued as rs782367838, COSV64339016; called by muse, mutect2, varscan2
